FM case AD12465 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/57a4a4cc-0c08-401a-86e2-e46583af0ec0

Female, 56.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the esophagus; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
